Gene-level copy-number profile of tumor specimen TCGA-IQ-A6SG-01A from TCGA case TCGA-IQ-A6SG, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 61.7 years (22,529 days).
Specimen TCGA-IQ-A6SG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.4cc327f7-0f15-4d67-bc99-c072595f1e25.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IQ-A6SG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6d35c2de-0109-4132-9c9f-38f84359c825

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 9; copy number 2: 8,986; copy number 3: 16,964; copy number 4: 18,714; copy number 5: 9,088; copy number 6: 3,247; copy number 7: 2,638; copy number 8: 33; copy number 11: 32; copy number 16: 2; copy number 18: 48; copy number 30: 6; copy number 58: 27; copy number 109: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IQ-A6SG-01A-12D-A34I-01): tumor purity 0.48, ploidy 3.75, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,966,929–21,995,301, 2 genes: CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.
- chr16:78,099,430–79,212,667, 1 gene (within-gene range 0–3): WWOX.
- chr16:78,166,717–78,873,505, 11 genes: AC009044.1, WWOX-AS1, AC106743.1, LSM3P5, AC046158.1, AC046158.4, AC046158.2, AC046158.3, AC009141.1, RPS3P7, AC136603.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 122 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:196,967,017–198,772,356, 27 genes, copy number 11 (within-gene range 7–11): ANKRD44, HNRNPA3P15, RPL4P7, ANKRD44-AS1, ANKRD44-IT1, ATP5MC2P3, AC010746.2, NPM1P46, SF3B1, AC010746.1, RNU6-1029P, COQ10B, HSPD1, HSPE1, HSPE1-MOB4, MOB4, AC020550.1, RFTN2, AC020550.2, AC011997.1, MARS2, BOLL, PLCL1, AC011997.2, AC020719.1, LINC01923, AC019330.1.
- chr2:204,379,095–205,620,162, 5 genes, copy number 11 (within-gene range 2–20): AC106901.1, AC016903.1, AC016903.2, PARD3B, AC007736.1.
- chr8:41,653,220–41,896,762, 1 gene, copy number 16 (within-gene range 5–30): ANK1.
- chr8:41,803,349–42,129,249, 7 genes, copy number 16–30: Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2.
- chr17:10,579,040–13,306,771, 48 genes, copy number 18: AC005323.1, MYH3, AC002347.1, SCO1, AC002347.2, ADPRM, TMEM220, MAGOH2P, TMEM220-AS1, AC015908.7, AC015908.3, AC015908.1, AC015908.4, AC015908.6, TMEM238L, AC015908.5, PIRT, AC015908.2, RNU6-1065P, RPL15P21, RN7SL601P, AC005548.1, SHISA6, AC005725.1, DNAH9, AC005209.1, AC005410.2, ZNF18, AC005410.1, MAP2K4, RNU11-2P, MIR744, AC005244.1, AC005244.2, AC084167.1, LINC00670, AC068442.1, MYOCD, MYOCD-AS1, AC005358.1, ARHGAP44, MIR1269B, AC005274.1, AC005277.2, AC005277.1, ELAC2, AC005303.1, LINC02093.
- chr18:25,953,216–27,595,164, 34 genes, copy number 58–109 (within-gene range 2–109): AC027229.1, SS18, RPS24P18, PSMA8, DHFRP1, NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P, LINC01543, KCTD1, AC007996.1, AC090206.1, MIR8057, CIAPIN1P, AQP4-AS1, AC012588.1, PCAT18, U3, AC018371.1, AC018371.2, AQP4, CHST9, ATP6V1E1P2, LINC01908, AC090403.1, AC021382.1, UBA52P9, AC068408.1, RBM22P1, PA2G4P3, AC068408.2.

Autosomal genes at a single copy (total copy number 1): 9. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
